Somatic mutation profile of tumor specimen MP2PRT-PAPFFT-TMP1-A (aliquot MP2PRT-PAPFFT-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPFFT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,514 days).
Specimen MP2PRT-PAPFFT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12b8bba2-0152-4d95-a917-761aae55fbe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFFT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFFT-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/955998ea-6aae-4c8f-bc5f-63793c933cab

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1315G>T p.V439F | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs760759247, COSV99710149; called by muse, mutect2, varscan2
- ASB10 | c.1241C>T p.S414F (on ENST00000420175 / NM_001142459.2; = p.S399F on NM_080871.4) | Missense Mutation (SNP) | VAF 15/391 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99318642; called by muse, mutect2
- BCAR1 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769103790, COSV50778721; called by muse, mutect2
- FAM189A1 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 53/623 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1472616450; called by muse, mutect2
- FLG | c.11654G>C p.R3885T | Missense Mutation (SNP) | VAF 28/509 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.346); catalogued as COSV100911490; called by muse, mutect2
- GRIK1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 42/436 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1214884120; called by muse, mutect2
- LOXHD1 | c.6216C>G p.I2072M (on ENST00000642948; = p.I2010M on NM_144612.7) | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.888); catalogued as COSV56066991; called by muse, mutect2
- NXPE1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 40/541 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV52633195; called by muse, mutect2
- PKHD1L1 | c.7571G>T p.G2524V | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV65738800, COSV99058742; called by muse, mutect2
- POU6F2 | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 46/547 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1293238993; called by muse, mutect2
- RARS1 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as COSV51562156, COSV51565564; called by muse, mutect2
- ASXL3 | c.1377G>C p.E459D | Missense Mutation (SNP) | VAF 29/309 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAM186A | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 20/387 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2
- GRID1 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 26/373 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- LRP12 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.143); called by muse, mutect2
- MAP3K13 | c.1787G>C p.R596T | Missense Mutation (SNP) | VAF 49/516 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MPND | c.639G>C p.K213N | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.197); called by muse, mutect2
- NMBR | c.982A>T p.S328C | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NXPE1 | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 45/513 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2
- P3H2 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PLCB4 | c.2473C>G p.P825A | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- PTCHD1 | c.2641G>T p.V881L | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PTPN21 | c.3316G>A p.V1106I | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2
- SRGAP1 | c.2476G>C p.D826H | Missense Mutation (SNP) | VAF 23/509 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- STON2 | c.2027T>C p.L676P (on ENST00000649389 / NM_001366849.2; = p.L619P on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TACR3 | c.1336T>C p.S446P | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY10 | c.1503G>A p.K501= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV100896638, COSV63240393; called by muse, mutect2
- KAZN | c.1245C>T p.P415= | Silent (SNP) | VAF 16/399 reads (4%) | called by muse, mutect2
- KIAA0513 | c.99C>T p.D33= | Silent (SNP) | VAF 44/484 reads (9%) | catalogued as rs780467555, COSV99261433; called by muse, mutect2
- KSR2 | c.654C>A p.A218= | Silent (SNP) | VAF 35/734 reads (5%) | called by muse, mutect2
- MYH14 | c.4767C>G p.L1589= | Silent (SNP) | VAF 50/456 reads (11%) | called by muse, mutect2, varscan2
- MYPN | c.3282T>C p.C1094= | Silent (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2, varscan2
- NPAP1 | c.894C>T p.S298= | Silent (SNP) | VAF 23/336 reads (7%) | catalogued as rs570658123, COSV61510828; called by muse, mutect2
- PRDM15 | c.411G>A p.K137= | Silent (SNP) | VAF 24/562 reads (4%) | catalogued as COSV54162724; called by muse, mutect2
- SLC6A16 | c.1797G>A p.T599= | Silent (SNP) | VAF 54/326 reads (17%) | catalogued as rs375922500; called by muse, mutect2, varscan2
- SYT10 | c.135G>A p.Q45= | Silent (SNP) | VAF 16/491 reads (3%) | catalogued as rs1295985517; called by muse, mutect2
- TENM4 | c.792C>T p.N264= | Silent (SNP) | VAF 22/424 reads (5%) | called by muse, mutect2
- TIGD1 | c.1656G>A p.R552= | Silent (SNP) | VAF 40/508 reads (8%) | called by muse, mutect2
- ZBED1 | c.399C>T p.L133= | Silent (SNP) | VAF 68/986 reads (7%) | catalogued as rs767728912; called by muse, mutect2
- SSH2 | c.64-54980G>C | Intron (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
